National Lung Screening Trial (NLST) participant 114994 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 58 years; Gender: female; Race: Native Hawaiian or Other Pacific Islander; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 34): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: limited CT, but interpretable (motion artifact); technique as recorded on the form: 120 kVp, 160 mA, display field of view 34 cm, reconstruction filter Toshiba FC51.
- T1 (day 398): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 160 mA, display field of view 33 cm, reconstruction filter Toshiba FC51.
- T2 (day 762): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 160 mA, display field of view 33 cm, reconstruction filter Toshiba FC51.

Abnormalities recorded by the reading radiologist on the CT screens (9 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 6 mm, longest perpendicular diameter 5 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 58.
- T1 abnormality 1: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 6 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation could not be determined; greatest diameter on CT slice 57; pre-existing on earlier images (earliest visible day 34); no interval growth; no suspicious change in attenuation.
- T1 abnormality 4: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 6 mm, longest perpendicular diameter 6 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 41; pre-existing on earlier images (earliest visible day 34); no interval growth; no suspicious change in attenuation.
- T1 abnormality 5: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation could not be determined; greatest diameter on CT slice 86; identified only on comparison with prior images; pre-existing on earlier images (earliest visible day 34); no interval growth; no suspicious change in attenuation.
- T1 abnormality 6: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation could not be determined; greatest diameter on CT slice 86; identified only on comparison with prior images; pre-existing on earlier images (earliest visible day 34); no interval growth; no suspicious change in attenuation.
- T2 abnormality 1: 6 or more nodules, not suspicious for cancer (opacity >= 4 mm).
- T2 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,582.
